Gene-level copy-number profile of tumor specimen TCGA-WR-A838-01A from TCGA case TCGA-WR-A838, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.3 years (26,418 days).
Specimen TCGA-WR-A838-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.19411d88-5575-4dbb-bdf2-1d0018c6a964.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WR-A838-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6910f2b1-b00c-423f-88c3-b582c9d8effe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,101; copy number 2: 4,689; copy number 3: 18,014; copy number 4: 21,749; copy number 5: 10,175; copy number 6: 912; copy number 7: 970; copy number 8: 718; copy number 9: 106; copy number 10: 30; copy number 11: 489; copy number 13: 123; copy number 14: 12; copy number 15: 81; copy number 17: 89; copy number 18: 255; copy number 19: 150; copy number 20: 85; copy number 21: 7; copy number 24: 42; copy number 31: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WR-A838-01A-12D-A402-01): tumor purity 0.95, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,482 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–150,913,292, 63 genes, copy number 19 (broad region; genes not listed).
- chr2:96,248,514–100,509,612, 99 genes, copy number 15–17 (broad region; genes not listed).
- chr8:39,309,909–41,032,998, 24 genes, copy number 9: AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P.
- chr8:121,113,358–122,127,184, 7 genes, copy number 10: AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3.
- chr8:123,768,439–130,443,674, 107 genes, copy number 15–19 (within-gene range 8–19) (broad region; genes not listed).
- chr8:133,573,183–137,092,183, 37 genes, copy number 13–21 (within-gene range 3–21): AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1.
- chr12:2,849,046–10,551,535, 324 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr12:15,322,257–15,882,329, 6 genes, copy number 9 (within-gene range 7–9): PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2.
- chr12:18,080,869–23,251,499, 75 genes, copy number 9–13 (broad region; genes not listed).
- chr12:24,212,421–33,455,452, 201 genes, copy number 9–31 (broad region; genes not listed).
- chr17:19,678,288–20,896,140, 66 genes, copy number 20–21 (broad region; genes not listed).
- chr17:20,894,532–20,902,680, 2 genes, copy number 20: RNU6-1178P, RNASEH1P1.
- chr18:6,729,716–6,915,716, 1 gene, copy number 13 (within-gene range 8–13): ARHGAP28.
- chr18:6,873,399–6,937,020, 4 genes, copy number 13: AP005210.1, LINC00668, SCML2P1, RNU6-916P.
- chr18:6,954,677–6,957,419, 1 gene, copy number 13: AP002409.1.
- chr18:31,447,741–36,279,119, 92 genes, copy number 11 (broad region; genes not listed).
- chr18:44,039,471–45,181,382, 12 genes, copy number 14: AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1.
- chr19:8,052,767–9,675,100, 73 genes, copy number 13 (within-gene range 7–13) (broad region; genes not listed).
- chr19:12,699,194–17,943,991, 288 genes, copy number 18–24 (within-gene range 7–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
